Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A3IE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A3IE-01A (Primary Tumor).

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH-GRADE (GRADE 3), INVASIVE INTO MUSCULARIS PROPRIA.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) BLADDER TUMOR - Multiple tan-pink irregular fragments of tissue (3.0 x 2.5 x 1.5 cm in aggregate), entirely submitted in A1-A2.

CLINICAL HISTORY

No history provided.

ICD-0-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, NOS C67.9
hw
12/8/11

Source: NCI Genomic Data Commons file 35d391a8-9137-4f8c-a9ef-51ad8dae1930 (TCGA-G2-A3IE.7412115B-6EA2-43B6-970B-F0ACDB77EAFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).